Gene-level copy-number profile of tumor specimen TCGA-IN-7808-01A from TCGA case TCGA-IN-7808, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 59.1 years (21,569 days).
Specimen TCGA-IN-7808-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6e71c046-54f3-49ae-a317-9775a2d3d434.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-7808-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29cd26e9-e93c-4805-ab55-a7664c616fe5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,774; copy number 2: 25,917; copy number 3: 15,220; copy number 4: 9,946; copy number 5: 3,120; copy number 6: 2,480; copy number 7: 815; copy number 8: 369; copy number 17: 10; copy number 20: 31; copy number 23: 27; copy number 29: 8; copy number 30: 51; copy number 35: 15; copy number 42: 10; copy number 45: 1; copy number 52: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-7808-01A-11D-2200-01): tumor purity 0.3, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr16:78,166,717–78,355,834, 4 genes: AC009044.1, WWOX-AS1, AC106743.1, LSM3P5.
- chr16:78,793,584–78,796,362, 1 gene: AC009141.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,951 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–169,630,193, 1,008 genes, copy number 5–6 (broad region; genes not listed).
- chr1:210,328,252–210,676,296, 1 gene, copy number 6 (within-gene range 4–6): HHAT.
- chr1:210,676,823–211,690,103, 24 genes, copy number 6: KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3, TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2.
- chr1:236,664,141–238,108,567, 21 genes, copy number 5 (within-gene range 4–5): ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9.
- chr2:59,218,680–60,554,467, 14 genes, copy number 5 (within-gene range 4–5): AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1.
- chr5:58,198–45,895,970, 710 genes, copy number 5–8 (broad region; genes not listed).
- chr7:70,972–127,253,093, 2,245 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 6: AC103955.1.
- chr9:85,369,591–138,203,325, 1,169 genes, copy number 6–7 (broad region; genes not listed).
- chr10:75,089,248–81,137,335, 127 genes, copy number 17–30 (broad region; genes not listed).
- chr11:28,679,183–37,702,220, 139 genes, copy number 6–52 (within-gene range 5–52) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).
- chr13:28,820,348–38,373,935, 139 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:40,079,106–40,535,807, 1 gene, copy number 5 (within-gene range 4–5): LINC00598.
- chr13:40,407,122–46,515,958, 141 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–13,996,443, 281 genes, copy number 5 (broad region; genes not listed).
- chr20:14,003,508–14,758,056, 9 genes, copy number 5: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:57,895,394–59,933,655, 52 genes, copy number 5 (within-gene range 4–5): AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2.
- chr21:28,743,208–29,288,205, 18 genes, copy number 6 (within-gene range 2–6): U6, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189.
- chr21:29,222,321–29,223,257, 1 gene, copy number 6: GAPDHP14.

Autosomal genes at a single copy (total copy number 1): 533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
